Somatic mutation profile of tumor specimen C3N-00852-01 (aliquot CPT0024650012) from CPTAC case C3N-00852, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 62.2 years (22,718 days).
Specimen C3N-00852-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77358007-1925-44a4-8530-59bfd9366f53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00852-71 (Blood Derived Normal), aliquot CPT0024740002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e755ee26-df2f-41f0-aa00-4bf58e326ff5

The open-access MAF lists 79 somatic variants for this specimen: 51 protein-altering or splice-affecting, 13 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 13, Intron 9, Frame Shift Del 8, Nonsense Mutation 3, 5'Flank 3, Splice Site 2, RNA 2, In Frame Ins 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP3M2 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51530271; called by muse, mutect2, varscan2
- COBLL1 | c.1256G>A p.R419H (on ENST00000392717; = p.R381H on NM_014900.5) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs149882271, COSV52063648; called by muse, mutect2, varscan2
- COL24A1 | c.2866C>A p.H956N | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as rs1157875253; called by muse, mutect2, varscan2
- DNAJB2 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1252580169; called by muse, mutect2, varscan2
- HSPA6 | c.1051T>A p.L351M | Missense Mutation (SNP) | VAF 120/283 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.99); catalogued as rs1179945729, COSV100554302, COSV59062758; called by muse, mutect2, varscan2
- INPP5F | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 44/133 reads (33%) | catalogued as COSV100739974; called by muse, mutect2, varscan2
- KIF1B | c.4118G>A p.R1373Q (on ENST00000377086 / NM_001365952.1; = p.R1327Q on NM_015074.3) | Missense Mutation (SNP) | VAF 136/465 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs774615554; called by muse, mutect2, varscan2
- N4BP1 | c.2628G>T p.Q876H | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV52210288; called by muse, mutect2, varscan2
- NDRG1 | c.602T>C p.M201T | Missense Mutation (SNP) | VAF 103/328 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs980031699; called by muse, mutect2, varscan2
- NPIPB11 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 71/777 reads (9%) | catalogued as rs1248418769; called by muse, mutect2, varscan2
- OVGP1 | c.173T>A p.F58Y | Missense Mutation (SNP) | VAF 204/433 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755771009; called by muse, mutect2, varscan2
- PBRM1 | c.1443+1del p.X481_splice | Splice Site (DEL) | VAF 102/229 reads (45%) | catalogued as COSV56270634; called by pindel, varscan2
- TOGARAM1 | c.4821_4824del p.L1607Ffs*12 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as rs749059577; called by pindel, varscan2
- TTN | c.3121G>A p.E1041K (on ENST00000591111; = p.E995K on NM_003319.4) | Missense Mutation (SNP) | VAF 51/267 reads (19%) | PolyPhen benign (0.013); catalogued as rs201869200, COSV60034296; called by muse, mutect2, varscan2
- VHL | c.469del p.T157Lfs*2 | Frame Shift Del (DEL) | VAF 196/381 reads (51%) | catalogued as COSV56565821; called by mutect2, pindel, varscan2
- AASDH | c.1913del p.F638Sfs*30 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | called by mutect2, pindel, varscan2
- ACACB | c.6034dup p.Y2012Lfs*6 | Frame Shift Ins (INS) | VAF 10/54 reads (19%) | called by mutect2, pindel
- ALOX12B | c.1441C>T p.L481F | Missense Mutation (SNP) | VAF 81/518 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- ARHGEF3 | c.1456_1458dup p.M486dup | In Frame Ins (INS) | VAF 99/161 reads (61%) | called by mutect2, pindel, varscan2
- ATP6V0A1 | c.665_674del p.I222Kfs*5 | Frame Shift Del (DEL) | VAF 28/81 reads (35%) | called by mutect2, pindel, varscan2
- CAPN5 | c.1811T>A p.V604E (on ENST00000456580; = p.V564E on NM_004055.5) | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- COL28A1 | c.2515A>C p.I839L | Missense Mutation (SNP) | VAF 180/371 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- CSF1R | c.148T>C p.W50R | Missense Mutation (SNP) | VAF 144/767 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLGAP2 | c.1738T>A p.Y580N | Missense Mutation (SNP) | VAF 86/252 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ERH | c.232A>C p.T78P | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, varscan2
- FLII | c.2047G>T p.E683* | Nonsense Mutation (SNP) | VAF 50/147 reads (34%) | called by muse, mutect2, varscan2
- FOXP2 | c.1229A>T p.H410L | Missense Mutation (SNP) | VAF 104/396 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- FSIP2 | c.13502del p.N4501Ifs*9 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- GJA9 | c.872A>C p.Q291P | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HIVEP3 | c.1903G>T p.G635C | Missense Mutation (SNP) | VAF 90/308 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- IGSF11 | c.220A>G p.I74V (on ENST00000393775 / NM_001015887.3; = p.I73V on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- IL4R | c.1912A>T p.I638F | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ISG20L2 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KDM5C | c.1549G>T p.D517Y | Missense Mutation (SNP) | VAF 163/210 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF7 | c.1405G>A p.V469I | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NLGN2 | c.602T>A p.L201Q | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- NTF3 | c.770del p.T257Nfs*14 | Frame Shift Del (DEL) | VAF 80/258 reads (31%) | called by mutect2, pindel, varscan2
- ODAM | c.56T>G p.I19S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- OR7A5 | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 91/331 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PLIN2 | c.449A>G p.E150G | Missense Mutation (SNP) | VAF 71/355 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PPP1R3B | c.476C>G p.T159S | Missense Mutation (SNP) | VAF 104/315 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- R3HDM1 | c.2645T>A p.L882H | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- RNF157 | c.297-1G>T p.X99_splice | Splice Site (SNP) | VAF 28/102 reads (27%) | called by muse, mutect2, varscan2
- RUNX2 | c.1060T>C p.S354P | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- SLC13A1 | c.1333C>G p.L445V | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- SSC5D | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 72/150 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D19 | c.1032del p.Y344* | Frame Shift Del (DEL) | VAF 11/62 reads (18%) | called by mutect2, pindel*, varscan2*
- TRA2B | c.710_714del p.S237Ifs*23 | Frame Shift Del (DEL) | VAF 63/146 reads (43%) | called by mutect2, pindel, varscan2
- TRPV6 | c.2024A>T p.D675V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- XYLB | c.45C>G p.F15L | Missense Mutation (SNP) | VAF 72/129 reads (56%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF597 | c.382C>G p.P128A | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- CDC16 | c.1525A>C p.R509= | Silent (SNP) | VAF 39/121 reads (32%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.1188G>A p.P396= (on ENST00000450689 / NM_001142749.3; = p.P229= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs751388859; called by muse, mutect2
- GPATCH1 | c.36G>C p.L12= | Silent (SNP) | VAF 41/327 reads (13%) | called by muse, mutect2, varscan2
- GPR162 | c.630C>A p.P210= | Silent (SNP) | VAF 48/155 reads (31%) | called by muse, mutect2, varscan2
- MAGI3 | c.3070C>T p.L1024= | Silent (SNP) | VAF 46/117 reads (39%) | called by muse, mutect2, varscan2
- MYPN | c.714G>A p.A238= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs757661676; ClinVar: likely benign; called by muse, mutect2, varscan2
- PHF23 | c.930A>G p.Q310= | Silent (SNP) | VAF 75/144 reads (52%) | called by muse, mutect2, varscan2
- PLK1 | c.978G>T p.S326= | Silent (SNP) | VAF 59/430 reads (14%) | called by muse, mutect2, varscan2
- R3HDM2 | c.1257C>A p.P419= | Silent (SNP) | VAF 108/216 reads (50%) | called by muse, varscan2
- SGCB | c.870T>C p.C290= | Silent (SNP) | VAF 112/246 reads (46%) | called by muse, mutect2, varscan2
- TAOK1 | c.414A>G p.G138= | Silent (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- TTC21B | c.2805T>C p.D935= | Silent (SNP) | VAF 147/491 reads (30%) | called by muse, mutect2, varscan2
- ZNF217 | c.792C>T p.D264= | Silent (SNP) | VAF 31/246 reads (13%) | catalogued as rs563819509; called by muse, mutect2, varscan2
- BNIP1 | c.490+785G>T | Intron (SNP) | VAF 19/164 reads (12%) | called by muse, mutect2, varscan2
- CZIB | c.6+100G>T | Intron (SNP) | VAF 68/202 reads (34%) | called by muse, mutect2, varscan2
- DPY19L2P2 | n.506C>G | RNA (SNP) | VAF 78/146 reads (53%) | called by muse, mutect2, varscan2
- DZANK1 | c.543+749G>T | Intron (SNP) | VAF 38/75 reads (51%) | called by muse, mutect2, varscan2
- EIF2B1 | c.482+170G>A | Intron (SNP) | VAF 42/141 reads (30%) | called by muse, mutect2, varscan2
- EPB41L3 | chr18:5630404 C>A | 5'Flank (SNP) | VAF 123/302 reads (41%) | catalogued as rs1272227389; called by muse, mutect2, varscan2
- FLT4 | c.3332-22del | Intron (DEL) | VAF 35/114 reads (31%) | catalogued as COSV99988381; called by mutect2, pindel, varscan2
- GGT7 | c.1726-126G>A | Intron (SNP) | VAF 65/222 reads (29%) | catalogued as rs760483256; called by muse, mutect2, varscan2
- HLA-L | n.992G>C | RNA (SNP) | VAF 15/120 reads (13%) | called by muse, mutect2
- INPP5B | c.772+13G>A | Intron (SNP) | VAF 103/218 reads (47%) | called by muse, mutect2, varscan2
- JPH3 | chr16:87701797 ins C | 3'Flank (INS) | VAF 80/260 reads (31%) | called by mutect2, pindel, varscan2
- RPS6KA1 | c.109-928G>C | Intron (SNP) | VAF 113/275 reads (41%) | called by muse, mutect2, varscan2
- SRRM2 | c.690-44T>A | Intron (SNP) | VAF 38/107 reads (36%) | called by muse, mutect2, varscan2
- WT1 | chr11:32439083 C>T | 5'Flank (SNP) | VAF 107/178 reads (60%) | called by muse, mutect2, varscan2
- WT1 | chr11:32439084 T>A | 5'Flank (SNP) | VAF 106/179 reads (59%) | called by muse, mutect2, varscan2
